Somatic mutation profile of tumor specimen C3N-01211-01 (aliquot CPT0075900009) from CPTAC case C3N-01211, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 59.4 years (21,688 days).
Specimen C3N-01211-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e69f2590-6034-42ad-b811-953b0b4d21ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01211-71 (Blood Derived Normal), aliquot CPT0076020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cfb65bc-c86d-47db-ac20-1ad336118d7e

The open-access MAF lists 459 somatic variants for this specimen: 335 protein-altering or splice-affecting, 76 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 76, Frame Shift Del 70, Intron 20, Frame Shift Ins 14, Nonsense Mutation 13, Splice Site 10, RNA 9, 5'Flank 8, 3'UTR 5, 5'UTR 5, Splice Region 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.6792dup p.A2265Rfs*8 | Frame Shift Ins (INS) | VAF 20/112 reads (18%) | catalogued as rs878855327; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 56/192 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 96/436 reads (22%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 55/174 reads (32%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 156/529 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761433545, COSV52748331; called by muse, mutect2, varscan2
- ABHD18 | c.42_44del p.L15del | In Frame Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs1266588013; called by mutect2, pindel, varscan2
- ABLIM1 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as rs1322528617, COSV53299667; called by muse, mutect2, varscan2
- AC244197.3 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs200694354, COSV61713566; called by muse, mutect2, varscan2
- ADRA2A | c.107del p.G36Afs*12 | Frame Shift Del (DEL) | VAF 80/225 reads (36%) | catalogued as rs1554870245; called by mutect2, pindel, varscan2
- ALLC | c.378+2T>C p.X126_splice | Splice Site (SNP) | VAF 26/72 reads (36%) | catalogued as rs773933562, COSV52996501; called by muse, mutect2, varscan2
- ANK2 | c.11555C>T p.A3852V | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.106); catalogued as COSV52167169; called by muse, mutect2, varscan2
- ANKRD35 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 170/711 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782138537, COSV62911229; called by muse, mutect2, varscan2
- APBA1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs759515322, COSV55231757, COSV55231856; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 92/282 reads (33%) | catalogued as rs758608743; called by mutect2, varscan2
- ATF7 | c.680C>T p.P227L (on ENST00000548446 / NM_001366555.2; = p.P216L on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs978219733, COSV60643919; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 112/341 reads (33%) | catalogued as rs35951843; called by mutect2, varscan2
- BAG6 | c.2965dup p.Q989Pfs*5 (on ENST00000676571; = p.Q942Pfs*5 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 44/126 reads (35%) | catalogued as rs778695310; called by mutect2, varscan2
- CACNA1A | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1057524457, COSV64196421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAP1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs373614963; called by muse, mutect2, varscan2
- CATSPERD | c.1466T>C p.I489T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs775543468; called by muse, mutect2, varscan2
- CBLL2 | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV60370806; called by muse, mutect2, varscan2
- CCDC185 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 93/439 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV64820336; called by muse, mutect2, varscan2
- CCER1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs1373415665; called by muse, mutect2, varscan2
- CDC42BPA | c.693G>T p.T231= | Splice Region (SNP) | VAF 20/91 reads (22%) | catalogued as COSV62001825; called by muse, mutect2, varscan2
- CDH12 | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as rs758315647; called by muse, mutect2, varscan2
- CDH7 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747775291, COSV59887025; called by muse, mutect2, varscan2
- CDH7 | c.1846T>C p.C616R | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59886522; called by muse, mutect2
- CDK5RAP3 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377021097; called by muse, mutect2, varscan2
- CDON | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as COSV54998303; called by muse, mutect2, varscan2
- CEBPA | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs974386262; called by muse, mutect2, varscan2
- CELSR3 | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771709882, COSV50884054; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs751492244; called by mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CLDN16 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.748); catalogued as rs757395583, CM085324; called by muse, mutect2, varscan2
- CPZ | c.163G>A p.A55T (on ENST00000360986 / NM_001014447.3; = p.A44T on NM_003652.3) | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs145429481; called by muse, mutect2, varscan2
- CR2 | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1165389618, COSV65508709; called by muse, mutect2, varscan2
- CXCR3 | c.769G>C p.V257L | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs770806154; called by muse, mutect2, varscan2
- DAB2IP | c.799C>T p.P267S (on ENST00000408936; = p.P239S on NM_032552.3) | Missense Mutation (SNP) | VAF 220/602 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1440857421; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 116/336 reads (35%) | catalogued as rs751187768; called by mutect2, varscan2
- DCHS1 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 102/248 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs781524621; called by muse, mutect2, varscan2
- DDX47 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs868464622; called by muse, mutect2, varscan2
- DLGAP2 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 161/454 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as rs532491856, COSV70095288; called by muse, mutect2, varscan2
- DOCK3 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as rs368447292; called by muse, mutect2, varscan2
- DOT1L | c.4036G>A p.G1346S | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as rs951636242; called by muse, mutect2, varscan2
- EBF1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.308); catalogued as rs909826089, COSV58180650; called by muse, mutect2, varscan2
- EEFSEC | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as rs753789877, COSV54625055; called by muse, mutect2, varscan2
- EIF4E1B | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs762675292; called by muse, mutect2, varscan2
- EIF4G1 | c.610T>A p.S204T (on ENST00000346169 / NM_198241.3; = p.S8T on NM_004953.5) | Missense Mutation (SNP) | VAF 252/693 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV100072013; called by muse, mutect2, varscan2
- ELFN1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 212/573 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs1259997471; called by muse, mutect2, varscan2
- EML6 | c.4070del p.K1357Rfs*9 | Frame Shift Del (DEL) | VAF 60/178 reads (34%) | catalogued as rs746682537; called by mutect2, varscan2
- FA2H | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 113/354 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs762343484; called by muse, mutect2, varscan2
- FAM120C | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60257468; called by muse, mutect2, varscan2
- FAM189A2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 234/729 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs770475612; called by muse, mutect2, varscan2
- FBRS | c.966_968dup p.A329dup (on ENST00000287468; = p.A849dup on NM_001105079.3) | In Frame Ins (INS) | VAF 122/678 reads (18%) | catalogued as rs755549582; called by mutect2, varscan2
- FCSK | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs756205868; called by muse, mutect2, varscan2
- GARNL3 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332708016, COSV59226978; called by muse, mutect2, varscan2
- GDPD2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as COSV65533335; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 62/194 reads (32%) | catalogued as rs763147690; called by mutect2, varscan2
- GLUD2 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 340/986 reads (34%) | catalogued as COSV100047089; called by muse, mutect2, varscan2
- GPR50 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs760818840; called by muse, mutect2, varscan2
- GSAP | c.2474-5dup | Splice Region (INS) | VAF 11/39 reads (28%) | catalogued as rs757049881; called by mutect2, varscan2
- GTF2IRD2 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782476504, COSV100736380; called by muse, mutect2, varscan2
- H3C11 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs1441556812; called by muse, mutect2, varscan2
- HAS1 | c.1464G>T p.W488C | Missense Mutation (SNP) | VAF 174/444 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55786308; called by muse, mutect2, varscan2
- HIF1A | c.2426G>A p.S809N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs754986249, COSV60190814; called by muse, mutect2, varscan2
- HLA-DQA1 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 200/304 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1168460423; called by muse, varscan2
- HMGCS2 | c.829del p.I277Sfs*22 | Frame Shift Del (DEL) | VAF 67/186 reads (36%) | catalogued as rs1557991740, COSV65568693; called by mutect2, pindel, varscan2
- HNRNPUL2 | c.296del p.P99Lfs*43 | Frame Shift Del (DEL) | VAF 63/222 reads (28%) | catalogued as rs1388106459; called by mutect2, pindel, varscan2
- IL18RAP | c.87del p.K29Nfs*66 | Frame Shift Del (DEL) | VAF 11/22 reads (50%) | catalogued as rs756319084; called by mutect2, pindel, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 141/235 reads (60%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 146/444 reads (33%) | catalogued as rs762230866, COSV99339624; called by mutect2, varscan2
- KANK3 | c.2202G>T p.M734I | Missense Mutation (SNP) | VAF 169/540 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100035509; called by muse, mutect2, varscan2
- KCNC4 | c.1409T>A p.V470D | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63925211; called by muse, mutect2, varscan2
- KCNS1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as COSV60259365; called by muse, mutect2, varscan2
- KCP | c.3218C>T p.P1073L (on ENST00000620378; = p.P1133L on NM_001366122.1) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52823210; called by muse, mutect2
- KDM4D | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1163149356, COSV58636974; called by muse, mutect2, varscan2
- KIF21A | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775802404; called by muse, mutect2, varscan2
- KIF3A | c.2078T>C p.V693A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0.052); catalogued as rs773535182; called by muse, mutect2, varscan2
- KLB | c.1403G>T p.W468L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57303444; called by muse, mutect2, varscan2
- KLHDC8A | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139968064; called by muse, mutect2, varscan2
- KLRK1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as rs774615042, COSV53698235; called by muse, mutect2, varscan2
- KMT2B | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs368744106; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 60/200 reads (30%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRT15 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs780820668; called by muse, mutect2, varscan2
- LATS2 | c.2987C>A p.P996H | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV66879494; called by muse, mutect2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs748571616; called by mutect2, varscan2
- LIG3 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1208843573; called by muse, varscan2
- LIMK1 | c.1718del p.P573Qfs*26 | Frame Shift Del (DEL) | VAF 71/231 reads (31%) | catalogued as COSV60284187; called by mutect2, pindel, varscan2
- LMAN1 | c.823-2dup p.X275_splice | Splice Site (INS) | VAF 28/104 reads (27%) | catalogued as rs765287063; called by mutect2, varscan2
- LOXHD1 | c.5986G>T p.G1996W (on ENST00000642948; = p.G1934W on NM_144612.7) | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56063816; called by muse, mutect2, varscan2
- LOXL4 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371771544; called by muse, mutect2, varscan2
- LRP3 | c.844T>C p.C282R | Missense Mutation (SNP) | VAF 113/390 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs758237488; called by muse, mutect2, varscan2
- MAPK4 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.022); catalogued as rs779269473, COSV101245336; called by muse, mutect2, varscan2
- MARCHF2 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1296853983; called by muse, mutect2, varscan2
- MCOLN1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 356/1016 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs1386018876; called by muse, mutect2, varscan2
- MMRN2 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs200709835; called by muse, mutect2, varscan2
- MTA2 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs769924403, COSV53469504; called by muse, mutect2, varscan2
- MTA3 | c.1681C>T p.R561W (on ENST00000405094 / NM_001330442.2; = p.R504W on NM_001282755.1) | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV101290759; called by muse, mutect2, varscan2
- MUC5B | c.8498C>T p.T2833I | Missense Mutation (SNP) | VAF 334/1339 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs1461127356; called by muse, mutect2, varscan2
- MXRA5 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs768847893, COSV54231645; called by muse, mutect2, varscan2
- MYEOV | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.043); catalogued as rs769099755, COSV58294849; called by muse, mutect2
- NBAS | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs751978680, COSV55715951; called by muse, mutect2, varscan2
- NDN | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100086167; called by muse, mutect2, varscan2
- NFASC | c.253G>A p.A85T (on ENST00000339876 / NM_001378329.1; = p.A79T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 275/574 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs769904507, COSV58365528; called by muse, mutect2, varscan2
- NOL4 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as rs960826327, COSV52341789; called by muse, mutect2, varscan2
- NOTCH3 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 254/923 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs201917592, COSV99655959, COSV99657834; called by muse, mutect2, varscan2
- NSMAF | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375678871; called by muse, mutect2, varscan2
- OR2G2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100189825; called by muse, mutect2, varscan2
- OTUD7A | c.2465C>T p.A822V (on ENST00000307050 / NM_001382637.1; = p.A815V on NM_130901.3) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.085); catalogued as rs1174556365; called by muse, mutect2, varscan2
- PANK3 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs776896383, COSV53323877; called by muse, mutect2, varscan2
- PCDH10 | c.2530C>T p.R844W | Missense Mutation (SNP) | VAF 117/319 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.65); catalogued as COSV52087916; called by muse, mutect2, varscan2
- PDZD4 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 129/346 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs782693675, COSV51250529, COSV99381322; called by muse, mutect2, varscan2
- PHOSPHO1 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56800207; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2G | c.192del p.F64Lfs*15 | Frame Shift Del (DEL) | VAF 30/79 reads (38%) | catalogued as COSV56841032; called by mutect2, pindel, varscan2
- PITPNM1 | c.2035G>A p.G679S | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs761557780; called by muse, mutect2, varscan2
- PLCE1 | c.6050C>T p.T2017M | Missense Mutation (SNP) | VAF 93/303 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs751230422; called by muse, mutect2, varscan2
- PLEKHD1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs899153016; called by muse, mutect2, varscan2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 79/262 reads (30%) | catalogued as rs751873496; called by mutect2, varscan2
- PMFBP1 | c.2078A>G p.Q693R (on ENST00000537465; = p.Q688R on NM_031293.3) | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.124); catalogued as CM142548; called by muse, mutect2, varscan2
- PNMT | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 148/392 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs762794960; called by muse, mutect2, varscan2
- PRKCSH | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 246/754 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs1283647745, COSV52953506; called by muse, mutect2, varscan2
- PRRC2A | c.3773G>A p.R1258Q | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745816832, COSV65687850; called by muse, mutect2, varscan2
- PRTG | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.02); catalogued as rs769696696, COSV66840156; called by muse, mutect2, varscan2
- RANBP10 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58156657; called by muse, mutect2, varscan2
- RAPGEF2 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100030610; called by muse, mutect2, varscan2
- RAPGEF2 | c.3259del p.I1087Ffs*98 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs760669443; called by mutect2, varscan2
- RBBP6 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1188555043, COSV60505021; called by muse, mutect2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBPMS2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55603568; called by muse, mutect2, varscan2
- RERE | c.3913C>T p.R1305W | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs1283210475, COSV61949416; called by muse, mutect2, varscan2
- RHPN2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 235/696 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs373249916; called by muse, mutect2, varscan2
- RYR3 | c.9764C>T p.A3255V (on ENST00000389232; = p.A3256V on NM_001036.6) | Missense Mutation (SNP) | VAF 94/361 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs775224723, COSV66785710; called by muse, mutect2, varscan2
- SAPCD2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs754400244; called by muse, mutect2, varscan2
- SCMH1 | c.748G>A p.D250N (on ENST00000326197 / NM_001031694.2; = p.D203N on NM_012236.4) | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.053); catalogued as rs372548251; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SGSM3 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 130/494 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755966818, COSV99960406; called by muse, mutect2, varscan2
- SLC25A39 | c.506C>T p.A169V (on ENST00000377095 / NM_001143780.3; = p.A161V on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.317); catalogued as rs750976898; called by muse, mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | catalogued as rs749889899; called by mutect2, varscan2
- SNRK | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs769334631; called by muse, mutect2, varscan2
- SNTG1 | c.649T>C p.S217P | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52459751; called by muse, mutect2, varscan2
- SPATA31E1 | c.490del p.D164Tfs*44 | Frame Shift Del (DEL) | VAF 68/175 reads (39%) | catalogued as COSV57792510; called by mutect2, pindel, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 101/366 reads (28%) | catalogued as rs771765677; called by mutect2, pindel, varscan2
- SPRR3 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 278/1012 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs1447484756; called by muse, varscan2
- SRP72 | c.25dup p.V9Gfs*9 | Frame Shift Ins (INS) | VAF 39/126 reads (31%) | catalogued as rs763130641; called by mutect2, varscan2
- SYNC | c.1307_1308del p.K436Rfs*11 | Frame Shift Del (DEL) | VAF 43/117 reads (37%) | catalogued as rs749756205; called by mutect2, pindel, varscan2
- TBC1D25 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 118/330 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as rs1556985297; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF4 | c.72+8_72+11del | Splice Region (DEL) | VAF 49/151 reads (32%) | catalogued as rs749161770; called by pindel, varscan2
- TCP11 | c.88del p.Q30Rfs*19 (on ENST00000512012; = p.Q30Rfs*14 on NM_001261817.2) | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs751330115; called by mutect2, pindel, varscan2
- TENM2 | c.5878C>T p.R1960C (on ENST00000518659 / NM_001122679.2; = p.R1721C on NM_001080428.3) | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as rs543591480; called by muse, mutect2, varscan2
- TFCP2L1 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.268); catalogued as rs376738163; called by muse, mutect2, varscan2
- TMEM145 | c.76del p.R26Afs*20 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | catalogued as rs1245316407; called by mutect2, varscan2
- TMEM202 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV58981941; called by muse, mutect2, varscan2
- TNKS | c.1664del p.N555Ifs*5 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as rs200458028; called by mutect2, pindel, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TRHDE | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV99670517; called by muse, mutect2, varscan2
- TSNAX | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as rs758573869, COSV64146126; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | catalogued as rs760251146; called by mutect2, varscan2
- UBASH3A | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 165/467 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs772379851; called by muse, mutect2, varscan2
- USP49 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1554143149, COSV51899401; called by muse, mutect2, varscan2
- VCAN | c.8797C>A p.Q2933K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99425703; called by muse, mutect2, varscan2
- WFIKKN1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1158527369, COSV99937735; called by muse, mutect2, varscan2
- YEATS2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs371729831; called by muse, mutect2, varscan2
- YTHDF3 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs368150163; called by muse, mutect2, varscan2
- ZBTB4 | c.2773G>A p.V925I | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as rs776394800; called by muse, mutect2, varscan2
- ZBTB5 | c.1999T>C p.W667R | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV57040777; called by muse, mutect2
- ZFHX3 | c.2096del p.G699Afs*125 | Frame Shift Del (DEL) | VAF 123/341 reads (36%) | catalogued as rs753977275, COSV51729347; called by mutect2, pindel, varscan2
- ZFP64 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs776570942; called by muse, mutect2
- ZNF800 | c.1322del p.K441Rfs*61 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs1346638445; called by mutect2, pindel, varscan2
- ZNF831 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as rs751452458, COSV64041559; called by muse, mutect2, varscan2
- ACTN2 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 351/678 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ADAM21 | c.1005del p.F335Lfs*9 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- ADAM23 | c.1345+1del p.X449_splice | Splice Site (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ADGRG4 | c.6431C>T p.A2144V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.17327G>T p.R5776M | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- AKAP3 | c.2551G>A p.V851M | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ALDH3A1 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 123/437 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ANKRD31 | c.4263del p.K1421Nfs*5 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- ANO9 | c.1746G>A p.W582* | Nonsense Mutation (SNP) | VAF 262/711 reads (37%) | called by muse, mutect2, varscan2
- AOC1 | c.568del p.R190Gfs*18 | Frame Shift Del (DEL) | VAF 148/487 reads (30%) | called by mutect2, pindel, varscan2
- ARID1A | c.4354del p.Q1452Rfs*29 | Frame Shift Del (DEL) | VAF 176/450 reads (39%) | called by mutect2, pindel, varscan2
- ASCC3 | c.6604A>C p.K2202Q | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by mutect2, varscan2
- ASTN1 | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 89/381 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATXN3 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 106/428 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, varscan2
- BCL6B | c.1434del p.*480Sfs*2 | Frame Shift Del (DEL) | VAF 153/430 reads (36%) | called by mutect2, pindel, varscan2
- BOP1 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1R | c.1430G>A p.R477H (on ENST00000536053 / NM_001354346.2; = p.R463H on NM_001733.7) | Missense Mutation (SNP) | VAF 266/737 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- CACNA1I | c.95dup p.S33Ifs*14 | Frame Shift Ins (INS) | VAF 187/663 reads (28%) | called by mutect2, pindel, varscan2
- CCDC142 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CCDC39 | c.661_662del p.Q221Rfs*4 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- CCDC62 | c.674A>T p.D225V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CD300LG | c.473del p.P158Qfs*3 | Frame Shift Del (DEL) | VAF 86/232 reads (37%) | called by mutect2, pindel, varscan2
- CDC73 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 92/425 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDK11B | c.99del p.K33Nfs*3 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | called by pindel, varscan2
- CEP170 | c.2815A>G p.S939G | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CHCHD4 | c.361G>A p.A121T (on ENST00000396914 / NM_001098502.2; = p.A134T on NM_144636.3) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNKSR3 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNN2 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 151/432 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNTN3 | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2
- CRACD | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 137/411 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- CROCC2 | c.1904A>G p.Q635R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DIP2C | c.2827C>A p.L943M | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- DNAH17 | c.12390del p.N4131Tfs*34 | Frame Shift Del (DEL) | VAF 93/229 reads (41%) | called by mutect2, pindel, varscan2
- DNAH3 | c.10953del p.I3652Sfs*14 | Frame Shift Del (DEL) | VAF 54/194 reads (28%) | called by mutect2, varscan2
- DNAH5 | c.5150T>C p.F1717S | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- DNAJC27 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- DNAJC5 | c.511A>C p.I171L | Missense Mutation (SNP) | VAF 281/949 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EOMES | c.579del p.G194Afs*94 | Frame Shift Del (DEL) | VAF 72/254 reads (28%) | called by pindel, varscan2
- EPHA5 | c.1184G>A p.C395Y | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPSTI1 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ESRP1 | c.1064del p.G355Efs*33 | Frame Shift Del (DEL) | VAF 60/176 reads (34%) | called by mutect2, pindel, varscan2
- FASTKD5 | c.500T>C p.L167S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- FAT3 | c.10476G>T p.E3492D | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT3 | c.12788T>C p.M4263T | Missense Mutation (SNP) | VAF 154/468 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FERMT2 | c.1586dup p.Y530Vfs*2 | Frame Shift Ins (INS) | VAF 31/78 reads (40%) | called by mutect2, pindel, varscan2
- FKRP | c.1484G>A p.G495D | Missense Mutation (SNP) | VAF 130/376 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FTCD | c.1195C>A p.R399S | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- FZD1 | c.1725G>T p.K575N | Missense Mutation (SNP) | VAF 123/330 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- GALNT12 | c.1459-2A>G p.X487_splice | Splice Site (SNP) | VAF 44/265 reads (17%) | called by muse, mutect2, varscan2
- GLB1L2 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- GLOD5 | c.46A>G p.R16G | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- GON4L | c.1146T>A p.D382E | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2
- HOXD13 | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFT88 | c.2182del p.M728* (on ENST00000319980 / NM_001318493.2; = p.M719* on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- IGSF6 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- INVS | c.2607G>T p.E869D | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGAM | c.2752C>A p.L918M (on ENST00000648685 / NM_001145808.2; = p.L917M on NM_000632.4) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- KCNH4 | c.2233C>A p.L745M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- KCTD15 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM4A | c.1107C>A p.C369* | Nonsense Mutation (SNP) | VAF 84/252 reads (33%) | called by muse, varscan2
- KDM4A | c.1163+1G>A p.X388_splice | Splice Site (SNP) | VAF 40/118 reads (34%) | called by muse, varscan2
- KIF20B | c.3395del p.N1132Mfs*11 (on ENST00000371728 / NM_001284259.2; = p.N1092Mfs*11 on NM_016195.4) | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel
- KLC1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KLHL5 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KLK10 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KMT2E | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- L3MBTL3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LAP3 | c.379+2T>C p.X127_splice | Splice Site (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- LARP1B | c.1648G>T p.G550* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2
- LOXL2 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRR1 | c.1007T>C p.I336T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- M6PR | c.809G>T p.R270M | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAG | c.212del p.P71Rfs*10 | Frame Shift Del (DEL) | VAF 86/278 reads (31%) | called by mutect2, varscan2
- MAP3K20 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- MAP4K4 | c.1841C>T p.A614V (on ENST00000347699 / NM_001242559.2; = p.A583V on NM_145686.3) | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD1 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 231/552 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MED12L | c.429del p.F143Lfs*4 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- MGAT5B | c.1578G>T p.K526N (on ENST00000569840 / NM_001199172.2; = p.K524N on NM_144677.3) | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MOV10L1 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MRC1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 170/492 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- MRPL24 | c.642T>A p.Y214* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- MYOC | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 90/671 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- MYORG | c.1669A>G p.N557D | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MYPOP | c.410del p.P137Lfs*151 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- MYPOP | c.72G>C p.E24D | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- NMUR1 | c.99dup p.H34Afs*3 | Frame Shift Ins (INS) | VAF 88/332 reads (27%) | called by mutect2, pindel, varscan2
- NOS3 | c.3350T>C p.V1117A | Missense Mutation (SNP) | VAF 178/565 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- OR51E2 | c.517C>A p.L173I | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- OR8S1 | c.440del p.G147Afs*16 | Frame Shift Del (DEL) | VAF 75/251 reads (30%) | called by mutect2, pindel, varscan2
- P3H1 | c.2135A>G p.D712G | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH1 | c.1454del p.P485Hfs*40 | Frame Shift Del (DEL) | VAF 77/232 reads (33%) | called by mutect2, pindel, varscan2
- PCDHB15 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 306/783 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PCDHGB3 | c.178del p.D60Ifs*18 | Frame Shift Del (DEL) | VAF 69/206 reads (33%) | called by mutect2, pindel, varscan2
- PCDHGC5 | c.1024del p.D342Mfs*19 | Frame Shift Del (DEL) | VAF 79/256 reads (31%) | called by mutect2, pindel, varscan2
- PGRMC2 | c.113del p.G38Efs*11 | Frame Shift Del (DEL) | VAF 125/405 reads (31%) | called by mutect2, pindel, varscan2
- PHACTR3 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHLPP2 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PIK3C2B | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R2 | c.1054T>G p.F352V | Missense Mutation (SNP) | VAF 123/394 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PLCB3 | c.2408del p.G803Vfs*4 | Frame Shift Del (DEL) | VAF 68/191 reads (36%) | called by mutect2, pindel, varscan2
- PLCXD1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNB3 | c.2233A>G p.I745V | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PNLDC1 | c.30del p.F10Lfs*9 | Frame Shift Del (DEL) | VAF 76/298 reads (26%) | called by mutect2, varscan2
- POLA2 | c.1660T>C p.C554R | Missense Mutation (SNP) | VAF 24/481 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- PPEF2 | c.1321dup p.V441Gfs*8 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- PPFIA4 | c.3415G>A p.A1139T (on ENST00000447715; = p.A1140T on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM10 | c.2922C>A p.Y974* | Nonsense Mutation (SNP) | VAF 87/229 reads (38%) | called by muse, mutect2, varscan2
- PRDM4 | c.1925-2A>G p.X642_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1094T>G p.V365G (on ENST00000352766; = p.V286G on NM_181334.5) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRRT4 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 152/454 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PTEN | c.969_996del p.N323Kfs*12 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- RASA4 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 52/866 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- RASEF | c.109T>A p.C37S | Missense Mutation (SNP) | VAF 222/652 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBL2 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- RBMX2 | c.480del p.D161Tfs*34 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- RTL1 | c.3619del p.Q1207Rfs*77 | Frame Shift Del (DEL) | VAF 34/83 reads (41%) | called by mutect2, pindel, varscan2
- SATB1 | c.94dup p.R32Pfs*38 | Frame Shift Ins (INS) | VAF 205/613 reads (33%) | called by mutect2, pindel, varscan2
- SCN10A | c.2783T>G p.L928R | Missense Mutation (SNP) | VAF 150/418 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- SCN8A | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEPTIN12 | c.727-2A>G p.X243_splice | Splice Site (SNP) | VAF 151/435 reads (35%) | called by muse, mutect2, varscan2
- SF3B3 | c.2573G>A p.G858D | Missense Mutation (SNP) | VAF 132/435 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SHLD2 | c.1301del p.N434Tfs*12 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- SIGLEC12 | c.1748C>T p.A583V (on ENST00000291707 / NM_053003.4; = p.A465V on NM_033329.2) | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- SIRPB2 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- SLC12A3 | c.1721C>A p.A574D | Missense Mutation (SNP) | VAF 107/408 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC39A7 | c.25del p.H9Tfs*8 | Frame Shift Del (DEL) | VAF 54/170 reads (32%) | called by mutect2, pindel, varscan2
- SLC5A5 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 49/823 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- SLFN14 | c.1126del p.S376Vfs*6 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- SMARCA2 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 54/202 reads (27%) | called by muse, mutect2, varscan2
- SOGA3 | c.2245del p.R749Afs*67 | Frame Shift Del (DEL) | VAF 93/247 reads (38%) | called by mutect2, pindel, varscan2
- SOGA3 | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 158/417 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SPPL2C | c.229del p.H77Tfs*21 | Frame Shift Del (DEL) | VAF 46/175 reads (26%) | called by mutect2, pindel, varscan2
- SRPK2 | c.1985T>G p.F662C | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST3GAL6 | c.968del p.N323Tfs*3 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- ST6GAL2 | c.1478A>G p.Q493R | Missense Mutation (SNP) | VAF 202/628 reads (32%) | PolyPhen benign (0.173); called by muse, mutect2, varscan2
- STAG1 | c.3167dup p.E1057* | Frame Shift Ins (INS) | VAF 41/181 reads (23%) | called by mutect2, pindel, varscan2
- STAG1 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SVIL | c.772G>C p.A258P | Missense Mutation (SNP) | VAF 119/309 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TAF4 | c.3090+2T>C p.X1030_splice | Splice Site (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- TBC1D10B | c.2366del p.P789Qfs*122 | Frame Shift Del (DEL) | VAF 155/385 reads (40%) | called by mutect2, pindel, varscan2
- TBC1D2B | c.1390G>T p.G464W | Missense Mutation (SNP) | VAF 119/329 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- TCERG1 | c.1635_1637del p.F546del | In Frame Del (DEL) | VAF 24/42 reads (57%) | called by pindel, varscan2
- TECPR2 | c.3931G>T p.G1311W | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THEMIS2 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TLE3 | c.422dup p.V142Gfs*42 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- TMEM249 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNK2 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 201/639 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TYMP | c.1159+7G>A | Splice Region (SNP) | VAF 61/159 reads (38%) | called by muse, mutect2, varscan2
- UBE2Z | c.959T>C p.I320T | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VAMP2 | c.29del p.P10Lfs*37 | Frame Shift Del (DEL) | VAF 80/225 reads (36%) | called by mutect2, pindel, varscan2
- VN1R5 | c.408del p.C137Afs*? | Frame Shift Del (DEL) | VAF 36/152 reads (24%) | called by mutect2, pindel, varscan2
- VPS9D1 | c.1396C>A p.H466N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.419); called by muse, varscan2
- VSIG10L | c.1474+2T>C p.X492_splice | Splice Site (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- WDR12 | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- WDR61 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC2HC1B | c.35dup p.N12Kfs*8 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- ZFHX2 | c.3974C>A p.P1325H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZMYM2 | c.3749del p.N1250Ifs*3 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | called by mutect2, varscan2
- ZMYM6 | c.2341A>G p.K781E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ZNF280A | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ZNF517 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ZNF610 | c.1044A>C p.E348D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABI3 | c.588G>T p.V196= | Silent (SNP) | VAF 179/513 reads (35%) | called by muse, mutect2, varscan2
- ACAP3 | c.1986C>T p.D662= | Silent (SNP) | VAF 100/279 reads (36%) | catalogued as rs1442563205; called by muse, mutect2, varscan2
- ACOX2 | c.552G>A p.T184= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as rs779275491; called by muse, mutect2, varscan2
- ADRA1D | c.639G>A p.A213= | Silent (SNP) | VAF 158/536 reads (29%) | catalogued as COSV101062850; called by muse, mutect2, varscan2
- ANAPC5 | c.1413C>T p.C471= | Silent (SNP) | VAF 81/241 reads (34%) | called by muse, mutect2, varscan2
- ANKRD18A | c.639A>G p.S213= | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- ATP2B3 | c.3582G>A p.T1194= | Silent (SNP) | VAF 154/413 reads (37%) | catalogued as rs1340229034; called by mutect2, varscan2
- AZGP1 | c.609G>A p.R203= | Silent (SNP) | VAF 98/274 reads (36%) | catalogued as rs754245509; called by muse, mutect2, varscan2
- B4GALT6 | c.559C>T p.L187= | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- BCL9 | c.1839C>T p.S613= | Silent (SNP) | VAF 85/362 reads (23%) | catalogued as rs782811475; called by muse, mutect2, varscan2
- BCORL1 | c.75C>A p.I25= | Silent (SNP) | VAF 63/227 reads (28%) | called by muse, mutect2, varscan2
- BICD2 | c.729G>A p.A243= | Silent (SNP) | VAF 265/818 reads (32%) | catalogued as rs200066450; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK5RAP3 | c.711G>A p.T237= | Silent (SNP) | VAF 94/330 reads (28%) | catalogued as rs757680785, COSV58114574; called by muse, varscan2
- CHST10 | c.462C>T p.N154= | Silent (SNP) | VAF 61/229 reads (27%) | catalogued as rs1487033030; called by muse, mutect2, varscan2
- CLIP4 | c.1980C>T p.S660= | Silent (SNP) | VAF 82/263 reads (31%) | catalogued as rs777100973, COSV60752829; called by muse, mutect2, varscan2
- COQ2 | c.207G>A p.A69= | Silent (SNP) | VAF 122/328 reads (37%) | called by muse, mutect2, varscan2
- CTDNEP1 | c.696C>T p.S232= | Silent (SNP) | VAF 83/275 reads (30%) | catalogued as rs142077609; called by muse, mutect2, varscan2
- CYP3A4 | c.993G>A p.L331= | Silent (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- DAG1 | c.24G>A p.S8= | Silent (SNP) | VAF 137/537 reads (26%) | catalogued as rs1229832209, COSV58186090; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCHS2 | c.1356T>C p.D452= | Silent (SNP) | VAF 44/148 reads (30%) | called by muse, mutect2, varscan2
- DGKZ | c.639G>A p.L213= | Silent (SNP) | VAF 150/379 reads (40%) | called by muse, mutect2, varscan2
- DNAH9 | c.2523T>C p.D841= | Silent (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- DPY19L1 | c.1734C>T p.D578= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs534879118, COSV100204684; called by muse, mutect2, varscan2
- EIF4E1B | c.609C>T p.H203= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs977195538; called by muse, mutect2, varscan2
- EMILIN2 | c.1431C>T p.G477= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as rs748210111, COSV54425830; called by muse, mutect2, varscan2
- EPN1 | c.1245G>A p.P415= (on ENST00000270460 / NM_001321263.1; = p.P389= on NM_013333.3) | Silent (SNP) | VAF 103/315 reads (33%) | catalogued as rs747408054, COSV50036198; called by muse, mutect2, varscan2
- FAM13B | c.717G>A p.E239= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs764102657; called by muse, mutect2
- FAM171A2 | c.1083C>T p.D361= | Silent (SNP) | VAF 167/506 reads (33%) | catalogued as COSV50007818, COSV50009118; called by muse, mutect2, varscan2
- FAT3 | c.9600G>A p.S3200= | Silent (SNP) | VAF 115/405 reads (28%) | catalogued as rs370683600; called by muse, mutect2, varscan2
- GDF9 | c.999C>T p.G333= | Silent (SNP) | VAF 58/152 reads (38%) | called by muse, mutect2, varscan2
- GLI1 | c.285G>A p.L95= | Silent (SNP) | VAF 91/333 reads (27%) | called by muse, mutect2, varscan2
- GPRC5C | c.1005C>A p.A335= (on ENST00000652232; = p.A290= on NM_018653.4) | Silent (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- GRM4 | c.2463G>A p.T821= | Silent (SNP) | VAF 76/211 reads (36%) | catalogued as rs1288904481; called by muse, mutect2, varscan2
- HLA-F | c.597G>A p.T199= | Silent (SNP) | VAF 96/222 reads (43%) | called by muse, mutect2, varscan2
- HS3ST5 | c.4C>T p.L2= | Silent (SNP) | VAF 57/156 reads (37%) | catalogued as rs756774453; called by muse, mutect2, varscan2
- HUNK | c.1720C>T p.L574= | Silent (SNP) | VAF 147/479 reads (31%) | called by muse, mutect2, varscan2
- IL17RA | c.1464G>A p.P488= | Silent (SNP) | VAF 329/984 reads (33%) | catalogued as rs368404830; called by muse, mutect2, varscan2
- IRS2 | c.3480C>T p.P1160= | Silent (SNP) | VAF 106/364 reads (29%) | catalogued as rs1031812964; called by muse, mutect2, varscan2
- KIAA1549 | c.675C>T p.S225= | Silent (SNP) | VAF 76/241 reads (32%) | catalogued as rs759452499, COSV99651515; called by muse, mutect2, varscan2
- LAX1 | c.1116C>T p.D372= | Silent (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- LIPK | c.741T>C p.N247= | Silent (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- LRP6 | c.2022C>T p.N674= | Silent (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- MMP15 | c.1359G>A p.P453= | Silent (SNP) | VAF 97/263 reads (37%) | catalogued as rs201292934, COSV54680088; called by muse, mutect2, varscan2
- MYOT | c.1455T>C p.R485= | Silent (SNP) | VAF 64/187 reads (34%) | called by muse, mutect2, varscan2
- PKD1L1 | c.1386C>T p.S462= | Silent (SNP) | VAF 26/60 reads (43%) | called by mutect2, varscan2
- PPP1R16B | c.594C>T p.N198= | Silent (SNP) | VAF 102/267 reads (38%) | catalogued as rs200868467, COSV55374057; called by muse, mutect2, varscan2
- ROBO3 | c.4017C>T p.S1339= | Silent (SNP) | VAF 129/442 reads (29%) | catalogued as rs972185683; called by muse, mutect2, varscan2
- RTEL1 | c.1158G>A p.T386= | Silent (SNP) | VAF 112/391 reads (29%) | catalogued as rs772026878; called by muse, mutect2, varscan2
- RUVBL1 | c.1329C>T p.S443= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as rs753870834; called by muse, mutect2, varscan2
- RXFP3 | c.426C>T p.N142= | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as rs770848896; called by muse, mutect2, varscan2
- SAMD4A | c.1815C>T p.N605= | Silent (SNP) | VAF 366/972 reads (38%) | catalogued as rs751788271; called by muse, mutect2, varscan2
- SCARA3 | c.21C>T p.G7= | Silent (SNP) | VAF 175/542 reads (32%) | catalogued as rs764823470, COSV57270615; called by muse, mutect2, varscan2
- SCN4A | c.1377C>T p.A459= | Silent (SNP) | VAF 121/375 reads (32%) | catalogued as rs781392555; called by muse, mutect2, varscan2
- SGK2 | c.39C>T p.G13= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as rs201979533, COSV58313126; called by muse, mutect2, varscan2
- SOX13 | c.1290C>A p.A430= | Silent (SNP) | VAF 85/422 reads (20%) | called by muse, mutect2, varscan2
- TCERG1 | c.597C>A p.A199= | Silent (SNP) | VAF 438/1199 reads (37%) | called by muse, mutect2, varscan2
- TRIO | c.7140C>T p.G2380= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs752358156; called by muse, mutect2, varscan2
- TRIP11 | c.5919G>T p.L1973= | Silent (SNP) | VAF 103/271 reads (38%) | catalogued as COSV99970336; called by muse, mutect2, varscan2
- TSPAN14 | c.240C>T p.C80= | Silent (SNP) | VAF 20/546 reads (4%) | catalogued as rs1046177887; called by muse, mutect2
- TXNRD2 | c.111G>A p.Q37= | Silent (SNP) | VAF 234/755 reads (31%) | catalogued as COSV57636004; called by muse, mutect2, varscan2
- UBA5 | c.804C>T p.N268= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs763860645; called by muse, mutect2, varscan2
- UBAP2L | c.2700G>A p.P900= | Silent (SNP) | VAF 145/880 reads (16%) | catalogued as rs763086547, COSV55173599; called by muse, mutect2, varscan2
- UBL4A | c.111A>G p.P37= | Silent (SNP) | VAF 154/469 reads (33%) | called by muse, mutect2, varscan2
- UGT1A8 | c.156G>A p.G52= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as rs938155548, COSV65078457; called by muse, mutect2, varscan2
- UNC80 | c.4089G>A p.L1363= | Silent (SNP) | VAF 45/136 reads (33%) | called by muse, mutect2, varscan2
- USH2A | c.13509G>T p.V4503= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- USP51 | c.537A>G p.L179= | Silent (SNP) | VAF 54/278 reads (19%) | called by muse, mutect2, varscan2
- VARS2 | c.513G>A p.R171= | Silent (SNP) | VAF 98/307 reads (32%) | called by muse, mutect2, varscan2
- ZC2HC1A | c.333T>A p.P111= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs759562783, COSV99804414; called by muse, mutect2, varscan2
- ZFP37 | c.417T>C p.V139= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- ZNF319 | c.660T>C p.H220= | Silent (SNP) | VAF 93/241 reads (39%) | catalogued as rs780730963; called by muse, mutect2, varscan2
- ZNF397 | c.99T>C p.D33= | Silent (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- ZNF440 | c.1680C>T p.Y560= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs766528860, COSV58371015; called by muse, mutect2, varscan2
- ZNF586 | c.924T>C p.H308= | Silent (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- ZNF726 | c.1512T>C p.T504= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs1009071201; called by muse, mutect2, varscan2
- ZNF853 | c.1368C>T p.A456= | Silent (SNP) | VAF 85/208 reads (41%) | catalogued as rs894423218; called by muse, mutect2, varscan2
- ABHD4 | chr14:22598122 G>T | 5'Flank (SNP) | VAF 83/222 reads (37%) | called by muse, mutect2, varscan2
- ADAM9 | c.410+31del | Intron (DEL) | VAF 34/104 reads (33%) | catalogued as rs557600780; called by mutect2, varscan2
- ARFGAP1 | c.835-252del | Intron (DEL) | VAF 141/431 reads (33%) | catalogued as rs774962385, COSV62263191; called by mutect2, pindel, varscan2
- ATP11AUN | n.976G>A | RNA (SNP) | VAF 36/99 reads (36%) | catalogued as rs200914561; called by muse, mutect2, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 27/67 reads (40%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- CCDC162P | n.1813-2645dup | Intron (INS) | VAF 90/248 reads (36%) | called by mutect2, pindel, varscan2
- CCNYL2 | n.624-2495C>T | Intron (SNP) | VAF 67/204 reads (33%) | catalogued as rs573457479; called by muse, mutect2, varscan2
- CEP120 | c.464-4060G>A | Intron (SNP) | VAF 12/56 reads (21%) | catalogued as rs1000094670, COSV60269004; called by muse, mutect2, varscan2
- CXCR4 | c.*24del | 3'UTR (DEL) | VAF 30/82 reads (37%) | catalogued as rs558791329; called by mutect2, varscan2
- DMD | c.-29del | 5'UTR (DEL) | VAF 23/75 reads (31%) | catalogued as rs398123823; ClinVar: likely benign; called by mutect2, varscan2
- FOXP2 | c.*1324del | 3'UTR (DEL) | VAF 11/36 reads (31%) | called by mutect2, varscan2
- GFAP | chr17:44915505 G>A | 5'Flank (SNP) | VAF 87/277 reads (31%) | catalogued as rs762416104; called by muse, mutect2, varscan2
- GJD4 | c.-13A>G | 5'UTR (SNP) | VAF 89/250 reads (36%) | called by muse, mutect2, varscan2
- GPM6B | chrX:13772912 C>T | 3'Flank (SNP) | VAF 16/33 reads (48%) | catalogued as rs142632459; called by muse, mutect2, varscan2
- HDAC4 | c.95-928C>A | Intron (SNP) | VAF 87/289 reads (30%) | catalogued as COSV61868763; called by muse, mutect2, varscan2
- IGKV1D-27 | n.163G>A | RNA (SNP) | VAF 70/244 reads (29%) | catalogued as rs1259042424; called by muse, mutect2, varscan2
- KIF17 | c.2020-47del | Intron (DEL) | VAF 115/374 reads (31%) | catalogued as rs1167738674; called by mutect2, pindel, varscan2
- LMF1 | c.1530-1128G>T | Intron (SNP) | VAF 234/634 reads (37%) | called by muse, mutect2, varscan2
- LRP5L | n.295C>A | RNA (SNP) | VAF 195/542 reads (36%) | called by muse, mutect2, varscan2
- LRRC9 | c.4131+709del | Intron (DEL) | VAF 19/70 reads (27%) | catalogued as rs1231009409; called by mutect2, pindel, varscan2
- LSM7 | c.6+32del | Intron (DEL) | VAF 28/274 reads (10%) | called by mutect2, pindel
- MPL | c.1565+48G>T | Intron (SNP) | VAF 61/184 reads (33%) | called by muse, mutect2, varscan2
- MYH9 | c.4933-30T>C | Intron (SNP) | VAF 131/391 reads (34%) | called by muse, mutect2, varscan2
- NDE1 | c.-64G>T | 5'UTR (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- NUP107 | c.-11A>G | 5'UTR (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- NUP153 | c.111+10C>A | Intron (SNP) | VAF 188/632 reads (30%) | catalogued as rs1472204691; called by muse, mutect2, varscan2
- OBSCN | c.9004+25C>T | Intron (SNP) | VAF 71/293 reads (24%) | called by muse, mutect2, varscan2
- OSGIN1 | n.850T>C | RNA (SNP) | VAF 56/146 reads (38%) | called by muse, mutect2, varscan2
- PCDHA5 | c.2352+28T>G | Intron (SNP) | VAF 57/148 reads (39%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.25-7784T>C | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- PRRT1 | c.20-187del | Intron (DEL) | VAF 38/129 reads (29%) | catalogued as rs1561801709; called by mutect2, varscan2
- PTENP1 | n.1816del | RNA (DEL) | VAF 43/140 reads (31%) | called by mutect2, pindel, varscan2
- PYY3 | n.118G>A | RNA (SNP) | VAF 225/638 reads (35%) | catalogued as rs1557200572; called by muse, mutect2, varscan2
- QPRT | chr16:29679132 C>T | 5'Flank (SNP) | VAF 35/203 reads (17%) | called by muse, mutect2, varscan2
- RN7SL319P | chr15:75781061 A>G | 5'Flank (SNP) | VAF 171/467 reads (37%) | catalogued as rs1351386647; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1487del | RNA (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- SHROOM2 | chrX:9786272 C>T | 5'Flank (SNP) | VAF 61/150 reads (41%) | catalogued as rs1185724789; called by muse, mutect2, varscan2
- SIX1 | chr14:60651907 del T | 5'Flank (DEL) | VAF 52/143 reads (36%) | catalogued as rs1460234182; called by mutect2, pindel, varscan2
- SNRNP27 | c.*30del | 3'UTR (DEL) | VAF 22/70 reads (31%) | catalogued as rs752687200; called by mutect2, varscan2
- SNUPN | c.-6+886del | Intron (DEL) | VAF 14/40 reads (35%) | catalogued as rs772102949; called by mutect2, varscan2
- SPATA31C1 | n.1938G>T | RNA (SNP) | VAF 97/318 reads (31%) | called by muse, mutect2, varscan2
- SPINK4 | c.*1T>C | 3'UTR (SNP) | VAF 35/103 reads (34%) | called by muse, mutect2, varscan2
- SSPOP | n.2610G>A | RNA (SNP) | VAF 174/517 reads (34%) | called by muse, mutect2, varscan2
- TCF4 | c.305-45del | Intron (DEL) | VAF 34/84 reads (40%) | catalogued as rs551539799; called by mutect2, varscan2
- WDR44 | c.-24del | 5'UTR (DEL) | VAF 116/371 reads (31%) | called by mutect2, pindel, varscan2
- WT1 | chr11:32439122 C>T | 5'Flank (SNP) | VAF 93/211 reads (44%) | called by muse, mutect2, varscan2
- YIPF6 | chrX:68498998 C>T | 5'Flank (SNP) | VAF 147/327 reads (45%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.*33del | 3'UTR (DEL) | VAF 84/265 reads (32%) | catalogued as rs759518581; called by mutect2, pindel, varscan2
